Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8332, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8332-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

W/o male with incidental right renal mass.

Specimens Submitted:

1: SP: Right kidney, adrenal gland and hilar lymph node

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, RIGHT RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CHROMOPHOBE CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 6.8 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- VASCULAR INVASION IS PRESENT. (SEE NOTE.)
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): RENAL HILAR: 0/1.

NOTE: A REPRESENTATIVE SLIDE WAS REVIEWED WITH DR. REUTER WHO CONCURS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

- 1) The specimen is received fresh, labeled "Right Kidney, Adrenal Gland and Hilar Lymph Node". It consists of a radical nephrectomy specimen, including right kidney, adrenal gland and attached perinephric adipose tissue, entirely weighing 550 grams and measuring 15 x 10 x 5.5 cm. The adrenal gland is identified and it measures 4.5 x 2 x 0.7 cm. It is separated from the renal parenchyma by 2.5 cm of perinephric adipose tissue. The adrenal gland is serially sectioned and appears grossly unremarkable. The ureter is identified and it measures 2 cm in length x 0.3 cm in diameter. Renal vessels are present and measure from 0.5 to 0.7 cm in length x 0.3 cm in diameter. The renal vessels and the distal ureter appear grossly unremarkable. Multiple hilar lymph nodes are identified, ranging in size from 0.3 to 0.5 cm. The kidney is bivalved revealing a well-circumscribed, partially encapsulated, tan-beige to light yellow mass measuring 6.8 x 6.5 x 3.8 cm located at the upper pole. Serial sectioning of the mass reveals cystic degeneration with very minimal hemorrhagic and necrotic areas. The cystic component comprises about 20% of the entire mass and the solid component comprises 80% of the mass. The mass is 0.7 cm from the renal pelvis. The mass appears to be confined within the renal parenchyma and within the renal capsule. No gross invasion of the vessels or perinephric fat is identified. The cortical-medullary junction is distinct. The cortical thickness ranges from 0.7 to 1 cm. The uninvolved renal parenchyma is tan-beige and appears grossly unremarkable. The renal capsule is easily stripped revealing a smooth

[page 2 of 2]
renocortical surface. The cortical surface is tan and smooth. Photographs are taken. Representative sections are submitted for EM and TPS. Representative sections are submitted.

Summary of Sections:

UM – ureter margin
RV – renal vessels
HLN – hilar lymph nodes
AG – adrenal gland closest to the kidney
RP – renal pelvis closest to the tumor
NK – normal-appearing kidney
T – tumor
PNF – closest perinephric fat

Summary of Sections:

Part 1: SP: Right kidney, adrenal gland and hilar lymph node

Block	Sect. Site	PCs
1	AG	2
1	HLN	2
2	NK	2
2	PNF	4
2	RP	2
1	RV	4
5	T	5
1	UM	1

Source: NCI Genomic Data Commons file c7214095-92bd-4234-bb9a-11100b6f2d90 (TCGA-KL-8332.4151B14A-435F-450D-B1DF-C27C050CE39C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).